Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1X6, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1X6-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination (cito)

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – left breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

1CD-0-3
carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos C50.9 bw 4/12/11

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 20.2 x 17.2 x 5.8 cm removed along with axillary tissues sized 8 x 5 x 3 cm and a skin flap of 21,4 x 15,4 cm. Weight 900 g.

Tumour sized 4.3 x 6.2 x 2.2 cm found in the upper outer quadrant, placed 1.2 cm from the upper boundary, 0.1 cm from the base and 0.5 cm from the skin.

Skin retraction 3 cm in diameter in the upper outer quadrant.

Microscopic description:

Carcinoma invasivum - NHG3 (3 + 3 + 3/20 mitoses/10 HPF - visual area 0.55 mm).

Infiltratio carcinomatosa cutis mammae.

Mamilla sine laesionibus.

Lesions of the type mastopathia fibrosa in the glandular tissue.

Axillary lymph nodes

Metastases carcinomatosae in lymphonodis (No V/VII).

Infiltratio telac perinodalis.

Histopathologic diagnosis:

Carcinoma ductale invasivum mammae sinistrae, invasive ductal carcinoma of the left breast.
Metastases carcinomatosae in lymphonodis (No XVII). Cancer metastases in the lymph nodes (No XVII)
(NHG3; pT3; pN2a).

CONTACT YOUR DOCTOR WITH

Source: NCI Genomic Data Commons file 6afc1bd0-c03a-4209-a0c6-d1cb700af862 (TCGA-D8-A1X6.880A4D38-40C5-46C3-8EE7-36539DD64773.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).